Somatic mutation profile of tumor specimen TCGA-05-4250-01A (aliquot TCGA-05-4250-01A-01D-1105-08) from TCGA case TCGA-05-4250, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 79.6 years (29,068 days).
Specimen TCGA-05-4250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3722e40f-ae0a-4d22-b64b-5aae459ac112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4250-10A (Blood Derived Normal), aliquot TCGA-05-4250-10A-01D-1105-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10c0500e-d828-4c4b-b574-2035ead37702

The open-access MAF lists 396 somatic variants for this specimen: 297 protein-altering or splice-affecting, 85 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 85, Nonsense Mutation 15, Frame Shift Del 10, Intron 8, Splice Site 6, RNA 4, In Frame Del 3, Frame Shift Ins 3, 3'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2B | c.7759C>T p.R2587* | Nonsense Mutation (SNP) | VAF 24/190 reads (13%) | catalogued as rs1555734923, COSV53073648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB5 | c.3170G>C p.S1057T (on ENST00000404938 / NM_001163941.2; = p.S612T on NM_178559.6) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51702996; called by muse, mutect2, varscan2
- ABCB6 | c.1825G>C p.V609L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs374541848, CM146894, COSV54692714; called by muse, mutect2, varscan2
- ACSL1 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 161/396 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55660602; called by muse, mutect2, varscan2
- ACTN2 | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142646143, COSV63971914; called by muse, mutect2, varscan2
- ADAMTS12 | c.4342G>T p.V1448L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61255511; called by muse, mutect2, varscan2
- ADCY10 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs752405771, COSV63238536; called by muse, mutect2, varscan2
- ADGRE2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV59691651; called by muse, mutect2, varscan2
- ADGRG4 | c.6930G>T p.L2310F | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV54949332; called by muse, mutect2, varscan2
- ADNP2 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs372177595; called by muse, mutect2, varscan2
- AFM | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV56918988; called by muse, mutect2, varscan2
- ALOX15 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748669056, COSV53396131, COSV53396254; called by muse, mutect2, varscan2
- ALPK3 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV51929288; called by muse, mutect2, varscan2
- ANGPT2 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1362916978, COSV57334909; called by muse, mutect2, varscan2
- AOC1 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100710756, COSV62866825; called by muse, mutect2, varscan2
- ARHGAP9 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV62721307; called by muse, mutect2, varscan2
- ATL2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV60050404; called by muse, mutect2, varscan2
- ATP11A | c.2372G>T p.C791F | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52106094; called by muse, mutect2, varscan2
- B4GALNT1 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs781534847, COSV57541184; called by muse, mutect2, varscan2
- BBS10 | c.1918A>T p.I640F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV67913048; called by muse, mutect2, varscan2
- BDP1 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.54); catalogued as COSV62428885; called by muse, mutect2, varscan2
- BPI | c.356G>T p.S119I (on ENST00000262865; = p.S115I on NM_001725.3) | Missense Mutation (SNP) | VAF 137/209 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV53403870; called by muse, mutect2, varscan2
- BRF1 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV59267023, COSV59274483; called by muse, mutect2, varscan2
- BRINP2 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100838220; called by muse, mutect2, varscan2
- BRINP3 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 35/199 reads (18%) | catalogued as COSV100818344; called by muse, mutect2, varscan2
- BRINP3 | c.1695G>T p.L565F | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100818345, COSV100819197; called by muse, mutect2, varscan2
- C10orf90 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 19/109 reads (17%) | catalogued as rs755351903, COSV52949494; called by muse, mutect2, varscan2
- C20orf96 | c.829A>T p.T277S (on ENST00000360321 / NM_153269.3; = p.T276S on NM_080571.1) | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.187); catalogued as COSV64402968; called by muse, mutect2, varscan2
- C3 | c.3343G>C p.D1115H | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM086785, COSV55568567, COSV55572808; called by muse, mutect2, varscan2
- C4BPA | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV65535697; called by muse, mutect2, varscan2
- C4orf51 | c.276G>A p.W92* | Nonsense Mutation (SNP) | VAF 61/160 reads (38%) | catalogued as COSV71263729; called by muse, mutect2, varscan2
- CAD | c.211G>C p.G71R | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53023558; called by muse, mutect2, varscan2
- CADM2 | c.1096G>C p.D366H (on ENST00000407528 / NM_001167674.2; = p.D368H on NM_153184.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101052820, COSV101054383; called by muse, mutect2, varscan2
- CAMK2B | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs748466047, COSV51657425; called by muse, mutect2, varscan2
- CAPN11 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV67236115; called by muse, mutect2, varscan2
- CARD11 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62753974; called by muse, mutect2, varscan2
- CASD1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs1245687472, COSV51970648; called by muse, mutect2, varscan2
- CASKIN2 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1193898003, COSV58592979; called by muse, mutect2, varscan2
- CCDC178 | c.1647G>T p.M549I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV55759333; called by muse, mutect2, varscan2
- CD300LB | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 309/627 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537689621, COSV58725107; called by muse, mutect2, varscan2
- CD8B | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV58924998; called by muse, mutect2, varscan2
- CDC25A | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56769713, COSV56770486; called by muse, mutect2, varscan2
- CDH11 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51751292, COSV51772173; called by muse, mutect2
- CEACAM1 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 62/474 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.445); catalogued as COSV50725473; called by muse, mutect2, varscan2
- CHRNB4 | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.251); catalogued as rs996194221, COSV55714644; called by muse, mutect2, varscan2
- CLEC12A | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV58562133; called by muse, varscan2
- CNTN2 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 197/597 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59348086; called by muse, mutect2, varscan2
- COL16A1 | c.499C>A p.R167S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV54701089, COSV54701553; called by muse, mutect2, varscan2
- COL6A1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV62611481; called by muse, mutect2, varscan2
- CRABP1 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55115376, COSV55115833; called by muse, mutect2, varscan2
- CREBBP | c.520G>C p.G174R | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV52114176; called by muse, mutect2, varscan2
- CRNN | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 63/431 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55120746; called by muse, mutect2, varscan2
- CRYBG2 | c.3663G>T p.K1221N | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57483712; called by muse, mutect2, varscan2
- CSMD1 | c.8897C>A p.S2966* (on ENST00000520002; = p.S2965* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV59281584; called by muse, mutect2, varscan2
- CST9 | c.443C>A p.A148E | Missense Mutation (SNP) | VAF 98/149 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as COSV100980453; called by muse, mutect2, varscan2
- CTAGE1 | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as rs762252148, COSV66942882; called by muse, mutect2, varscan2
- CTH | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61007360, COSV61007706; called by muse, mutect2, varscan2
- CTNNA2 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 140/230 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58134507; called by muse, mutect2, varscan2
- CUL1 | c.1216A>C p.N406H | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57386686; called by muse, mutect2, varscan2
- DACH1 | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV57489486; called by muse, mutect2, varscan2
- DDR1 | c.988A>G p.R330G | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV61319022; called by muse, mutect2, varscan2
- DKK2 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53393881, COSV53403906; called by muse, mutect2, varscan2
- DNAJC3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1248122483, COSV65130485; called by muse, mutect2, varscan2
- DOK5 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV52816570; called by muse, mutect2, varscan2
- DPH6 | c.383A>T p.N128I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56612566; called by muse, mutect2, varscan2
- DPYS | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV60906386, COSV60911578; called by muse, mutect2, varscan2
- DYNC2I1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV68103574; called by muse, mutect2, varscan2
- E2F1 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55774486; called by muse, mutect2, varscan2
- EFL1 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV51602724; called by muse, mutect2, varscan2
- EGLN3 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV99164286; called by muse, mutect2, varscan2
- EGLN3 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99164287; called by muse, mutect2, varscan2
- ELP4 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1212967030, COSV99540664; called by muse, mutect2, varscan2
- EXT1 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.193); catalogued as COSV65475001; called by muse, mutect2, varscan2
- FAM153B | c.715G>T p.E239* (on ENST00000253490; = p.E162* on NM_001265615.1) | Nonsense Mutation (SNP) | VAF 40/516 reads (8%) | catalogued as COSV99498735; called by muse, mutect2
- FCGBP | c.5740G>C p.G1914R | Missense Mutation (SNP) | VAF 44/966 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55433481; called by muse, mutect2
- FCRL3 | c.1536C>G p.H512Q | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV63839424; called by muse, mutect2, varscan2
- FMO1 | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141233517, COSV61444634; called by muse, mutect2, varscan2
- FMO5 | c.979A>T p.I327F | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as rs1553920917, COSV54204478; called by muse, mutect2, varscan2
- FRG1 | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs753957739, COSV99902363; called by muse, varscan2
- FRY | c.694A>C p.I232L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV66565117; called by muse, mutect2, varscan2
- FXYD5 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 88/154 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV100732574; called by muse, mutect2, varscan2
- FYCO1 | c.2794G>C p.E932Q | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as COSV56113496; called by muse, mutect2, varscan2
- GARNL3 | c.1959del p.M654Wfs*2 | Frame Shift Del (DEL) | VAF 43/115 reads (37%) | catalogued as COSV59229646; called by mutect2, pindel, varscan2
- GLI3 | c.2654G>T p.R885L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV67885243; called by muse, mutect2, varscan2
- GLP2R | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52321936; called by muse, mutect2, varscan2
- GPR149 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV67665783; called by muse, mutect2, varscan2
- GPR15 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.053); catalogued as COSV52520005, COSV99423881; called by muse, mutect2, varscan2
- GPR50 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 158/313 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV54436869; called by muse, mutect2, varscan2
- GREM2 | c.216G>C p.W72C | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781668325, COSV100547290; called by muse, mutect2, varscan2
- HDAC9 | c.2370G>T p.M790I | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101286224; called by muse, mutect2, varscan2
- HDAC9 | c.2371G>T p.G791W | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101286226, COSV67769759; called by muse, mutect2, varscan2
- HEATR1 | c.2455A>G p.K819E | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV63979794; called by muse, mutect2, varscan2
- HEPHL1 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV59889439, COSV59892109; called by mutect2, varscan2
- HERC2 | c.6899A>G p.K2300R | Missense Mutation (SNP) | VAF 123/323 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV55307467; called by muse, mutect2, varscan2
- HHAT | c.899A>T p.Y300F | Missense Mutation (SNP) | VAF 62/520 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54791205, COSV54791368; called by muse, mutect2, varscan2
- HRH3 | c.418-1G>T p.X140_splice | Splice Site (SNP) | VAF 68/105 reads (65%) | catalogued as COSV100420437; called by muse, mutect2, varscan2
- HRNR | c.1318G>T p.G440C | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64254076; called by muse, mutect2, varscan2
- HSPG2 | c.11048A>C p.Y3683S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65932690; called by muse, mutect2, varscan2
- IGKV1-27 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs565138312; called by muse, mutect2, varscan2
- IKZF5 | c.576C>A p.S192R | Missense Mutation (SNP) | VAF 75/404 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.102); catalogued as COSV64397186; called by muse, mutect2, varscan2
- IL12RB2 | c.665-1G>T p.X222_splice | Splice Site (SNP) | VAF 15/74 reads (20%) | catalogued as COSV52020248; called by muse, mutect2, varscan2
- IL12RB2 | c.2536G>C p.D846H | Missense Mutation (SNP) | VAF 204/807 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV52020261; called by muse, mutect2, varscan2
- IL7R | c.1356G>T p.M452I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57405735; called by muse, mutect2, varscan2
- ITGAX | c.3169C>A p.R1057S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51641457; called by muse, varscan2
- JAK2 | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67576267; called by muse, mutect2, varscan2
- KCNB2 | c.2369A>C p.K790T | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.114); catalogued as COSV73048893; called by muse, mutect2, varscan2
- KEL | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV62333250; called by muse, mutect2, varscan2
- KIAA0825 | c.812T>C p.M271T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100265563; called by muse, mutect2, varscan2
- KIAA1549L | c.4511G>T p.G1504V (on ENST00000321505; = p.G1801V on NM_012194.3) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100380862; called by muse, mutect2, varscan2
- KIF18B | c.2212G>T p.E738* (on ENST00000593135 / NM_001265577.2; = p.E750* on NM_001264573.2) | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV59270741; called by muse, mutect2
- KIF19 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as rs750922384, COSV100738943; called by muse, mutect2, varscan2
- KIF1A | c.4441T>A p.C1481S (on ENST00000320389 / NM_001379639.1; = p.C1473S on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV57482644; called by muse, mutect2, varscan2
- KIR3DL3 | c.304T>A p.S102T | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.331); catalogued as COSV99399707; called by muse, mutect2, varscan2
- KLHDC9 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 84/496 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs769478249, COSV63509231; called by muse, mutect2, varscan2
- KLK14 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 166/773 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV50067917; called by muse, mutect2, varscan2
- KMT2E | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.97); catalogued as COSV57569515; called by muse, mutect2, varscan2
- KRT33B | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs747784843, COSV52440540; called by muse, mutect2, varscan2
- KRT72 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53373193; called by muse, mutect2
- LAMA5 | c.3619A>T p.I1207F | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV53352903; called by muse, mutect2, varscan2
- LAMB2 | c.4550A>C p.Q1517P | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV59730741; called by muse, mutect2, varscan2
- LAMB2 | c.3192G>T p.Q1064H | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59730750; called by muse, mutect2, varscan2
- LARP1 | c.3056G>A p.R1019Q (on ENST00000518297 / NM_033551.3; = p.R942Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs770314875, COSV60424606; called by muse, mutect2, varscan2
- LGR6 | c.2354T>A p.L785H (on ENST00000367278 / NM_001017403.1; = p.L733H on NM_021636.3) | Missense Mutation (SNP) | VAF 154/275 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55151462; called by muse, mutect2, varscan2
- LIPE | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 269/456 reads (59%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV54921277; called by muse, mutect2, varscan2
- MAGEA4 | c.632C>A p.A211E | Missense Mutation (SNP) | VAF 120/263 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV99367274; called by muse, mutect2, varscan2
- MANEA | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV100721441; called by muse, mutect2, varscan2
- MAP3K1 | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV68121752; called by muse, mutect2, varscan2
- MBOAT1 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61123525; called by muse, mutect2, varscan2
- MC5R | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 109/237 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61253897; called by muse, mutect2, varscan2
- MCCC2 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.031); catalogued as COSV60152805; called by muse, mutect2, varscan2
- MED13 | c.3039G>C p.R1013S | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.977); catalogued as COSV67261902, COSV67265877; called by muse, mutect2, varscan2
- MFSD10 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296007; called by muse, mutect2, varscan2
- MGAT4C | c.1218G>T p.L406F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59829893; called by muse, mutect2, varscan2
- MMP13 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.607); catalogued as COSV52823063; called by mutect2, varscan2
- MUC16 | c.30838C>G p.P10280A | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as COSV67444613; called by muse, mutect2, varscan2
- MYBPC3 | c.1537A>G p.I513V | Missense Mutation (SNP) | VAF 159/262 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV57022958; called by muse, mutect2, varscan2
- N4BP2 | c.4414T>G p.L1472V | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.45); catalogued as COSV54698917; called by muse, mutect2, varscan2
- NAT2 | c.20T>A p.F7Y | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV54061176; called by muse, mutect2, varscan2
- NAV2 | c.4163C>T p.S1388F (on ENST00000396087 / NM_001244963.2; = p.S1365F on NM_145117.5) | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV60656423; called by muse, mutect2, varscan2
- NCOR2 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62293079; called by muse, mutect2, varscan2
- NDUFA9 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56927720; called by muse, mutect2, varscan2
- NEK2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV65355177; called by muse, mutect2
- NIPBL | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV56942286; called by muse, mutect2, varscan2
- NLRP5 | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 104/446 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375006739; called by muse, mutect2, varscan2
- NMNAT3 | c.461A>G p.Q154R (on ENST00000296202 / NM_001320512.1; = p.Q117R on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.51); catalogued as rs752859159, COSV56154849; called by muse, mutect2, varscan2
- NOM1 | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51978844; called by muse, mutect2, varscan2
- NOTCH4 | c.2751C>A p.H917Q | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV66678701; called by muse, mutect2, varscan2
- NOTCH4 | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 94/436 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1271531409, COSV66678705; called by muse, mutect2, varscan2
- NPC1L1 | c.3056G>T p.R1019L | Missense Mutation (SNP) | VAF 252/735 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV56922427; called by muse, mutect2, varscan2
- NTRK3 | c.942G>T p.E314D | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV58109711; called by muse, mutect2, varscan2
- NXPH4 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs758047263, COSV61073150; called by muse, mutect2, varscan2
- OAZ3 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV100162320; called by muse, mutect2, varscan2
- OBSCN | c.5612G>A p.R1871H | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs373897702; called by muse, mutect2, varscan2
- OR2A12 | c.757A>G p.S253G | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV68821033; called by muse, mutect2, varscan2
- OR2A25 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV68716856, COSV68717061; called by muse, mutect2, varscan2
- OR2G3 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV60680781; called by muse, mutect2, varscan2
- OR2L3 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 147/402 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV63454425; called by muse, mutect2, varscan2
- OR2M3 | c.382C>G p.H128D | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV71758853; called by muse, mutect2, varscan2
- OR5AP2 | c.192del p.M65Cfs*11 | Frame Shift Del (DEL) | VAF 44/117 reads (38%) | catalogued as COSV57256925; called by mutect2, pindel, varscan2
- OR5L2 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV65723368; called by muse, mutect2, varscan2
- OR6F1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100128947, COSV100129380; called by muse, mutect2, varscan2
- OR6F1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100128948; called by muse, mutect2, varscan2
- OTOF | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV55495530; called by muse, mutect2, varscan2
- P4HA2 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 116/301 reads (39%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.886); catalogued as COSV51323772; called by muse, mutect2, varscan2
- PALD1 | c.1630T>C p.W544R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54970715; called by muse, mutect2
- PALLD | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV54972870; called by muse, mutect2, varscan2
- PALLD | c.1050C>G p.S350R | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.945); catalogued as rs569927452, COSV54972891; called by muse, mutect2, varscan2
- PCDH15 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs767966376, COSV57263373; called by muse, mutect2, varscan2
- PCDHB9 | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53375358; called by muse, mutect2, varscan2
- PCDHGA5 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53898317; called by muse, mutect2, varscan2
- PCDHGC4 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV52742843; called by muse, mutect2, varscan2
- PCK1 | c.799-1G>T p.X267_splice | Splice Site (SNP) | VAF 66/201 reads (33%) | catalogued as COSV60126129; called by muse, mutect2, varscan2
- PCNX1 | c.5107-2A>T p.X1703_splice | Splice Site (SNP) | VAF 39/100 reads (39%) | catalogued as COSV53089160; called by muse, varscan2
- PER1 | c.2255C>G p.P752R | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.63); catalogued as rs748967347, COSV57917307; called by muse, mutect2, varscan2
- PES1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58827904; called by muse, mutect2, varscan2
- PIK3C2B | c.3574G>T p.G1192C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV65808996; called by muse, mutect2, varscan2
- PKD1L2 | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV55158068; called by muse, mutect2, varscan2
- PLEKHG2 | c.4057A>G p.K1353E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as COSV52678354; called by muse, mutect2, varscan2
- PLXNA1 | c.5399T>A p.L1800Q | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52522140; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1040G>C p.G347A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as COSV100982341; called by muse, mutect2, varscan2
- PPARGC1B | c.2495C>G p.S832C | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV58525968; called by muse, mutect2, varscan2
- PPIP5K2 | c.3659C>T p.S1220L (on ENST00000358359 / NM_001276277.3; = p.S1199L on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs1426299142, COSV58602451; called by muse, mutect2, varscan2
- PPP1R15B | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 120/460 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV65815305; called by mutect2, varscan2
- PRKDC | c.2706A>T p.K902N | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58042677; called by muse, mutect2, varscan2
- PRKRA | c.544A>T p.R182W | Missense Mutation (SNP) | VAF 27/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57867696; called by muse, mutect2
- PRLHR | c.484G>C p.V162L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV99492645; called by muse, mutect2, varscan2
- PSG5 | c.952G>T p.V318F | Missense Mutation (SNP) | VAF 348/640 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV61653471; called by muse, mutect2, varscan2
- PTGDR2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57126646; called by muse, mutect2, varscan2
- PTGFRN | c.1386G>T p.E462D | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as COSV67797704; called by muse, mutect2, varscan2
- RAB34 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99972513; called by muse, mutect2
- RAD51AP2 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV67587307; called by muse, mutect2, varscan2
- RGS7 | c.79-1G>A p.X27_splice | Splice Site (SNP) | VAF 22/77 reads (29%) | catalogued as COSV58530854; called by muse, mutect2, varscan2
- RHEB | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV51262446; called by muse, mutect2, varscan2
- RNF165 | c.890G>T p.C297F | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53971098; called by muse, mutect2, varscan2
- ROPN1B | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.66); catalogued as COSV52541677; called by muse, mutect2, varscan2
- RP1L1 | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV66751628; called by muse, mutect2, varscan2
- RPL3 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as COSV53364671; called by muse, mutect2, varscan2
- RXFP1 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57046737; called by muse, mutect2, varscan2
- SCAPER | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | catalogued as COSV100237200; called by muse, mutect2, varscan2
- SCG3 | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.301); catalogued as COSV51056642; called by muse, mutect2, varscan2
- SEC24D | c.1771G>T p.G591W | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54876709; called by muse, mutect2, varscan2
- SERPINB3 | c.857G>C p.R286P | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52189793; called by muse, mutect2, varscan2
- SET | c.218A>G p.Y73C (on ENST00000372692 / NM_001374326.1; = p.Y60C on NM_003011.4) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV100433019; called by muse, mutect2, varscan2
- SETD1A | c.607A>T p.K203* | Nonsense Mutation (SNP) | VAF 62/147 reads (42%) | catalogued as COSV52684961; called by muse, mutect2
- SETD1A | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV52684974, COSV52685772; called by muse, mutect2
- SGCD | c.780C>G p.F260L (on ENST00000435422 / NM_001128209.2; = p.F261L on NM_000337.5) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV61903980, COSV61905794; called by muse, mutect2, varscan2
- SH3TC2 | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 175/444 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100101190, COSV60464862; called by muse, mutect2, varscan2
- SLC24A3 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 113/189 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as COSV100041723, COSV60111523; called by muse, mutect2, varscan2
- SLC24A4 | c.1254G>A p.P418= | Splice Region (SNP) | VAF 16/83 reads (19%) | catalogued as rs761242671, COSV54107132; called by muse, mutect2, varscan2
- SLC24A4 | c.1729C>G p.H577D | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54107159; called by muse, mutect2, varscan2
- SLC25A37 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs993933461, COSV51563137, COSV99263965; called by muse, mutect2
- SLC28A2 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV61663195; called by muse, mutect2, varscan2
- SLC35A5 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53726052; called by muse, mutect2, varscan2
- SLC43A1 | c.1055-2A>T p.X352_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as COSV53557514; called by muse, mutect2, varscan2
- SLC6A15 | c.2072G>C p.G691A | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV57020043; called by muse, mutect2, varscan2
- SLC7A13 | c.65T>C p.L22S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52532429; called by muse, mutect2, varscan2
- SLITRK2 | c.1636C>A p.H546N | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV59423076; called by muse, mutect2, varscan2
- SMARCB1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV53155373; called by muse, mutect2, varscan2
- SMYD1 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV70224427; called by muse, mutect2, varscan2
- SOHLH2 | c.200T>C p.M67T | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV58520706; called by muse, mutect2, varscan2
- SPDYE3 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs754815513, COSV100193352; called by muse, mutect2, varscan2
- SPTA1 | c.5671C>T p.Q1891* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV63748920; called by muse, mutect2, varscan2
- SRGAP1 | c.1481G>T p.R494M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV61894399; called by muse, mutect2, varscan2
- SUGCT | c.1271G>T p.G424V (on ENST00000335693 / NM_001193313.2; = p.G450V on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59314074; called by muse, mutect2, varscan2
- SULF2 | c.723C>A p.N241K | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63413882, COSV63420555; called by muse, mutect2, varscan2
- SUSD4 | c.1227G>C p.Q409H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV59549823; called by muse, mutect2, varscan2
- SVEP1 | c.8252G>T p.G2751V | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52835408; called by muse, mutect2, varscan2
- SZT2 | c.8054A>T p.Q2685L (on ENST00000634258 / NM_001365999.1; = p.Q2628L on NM_015284.4) | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV100987353, COSV65167195; called by muse, mutect2, varscan2
- TACC3 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs757267468, COSV57602741; called by muse, mutect2, varscan2
- TAF5L | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 81/265 reads (31%) | catalogued as COSV51077330; called by muse, mutect2, varscan2
- TANC2 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67330127; called by muse, mutect2
- TASOR | c.2185A>G p.N729D (on ENST00000355628 / NM_001365636.2; = p.N333D on NM_015224.3) | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100843336; called by muse, varscan2
- TBX3 | c.1117G>A p.G373S (on ENST00000257566 / NM_016569.4; = p.G353S on NM_005996.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.26); catalogued as COSV57469258; called by muse, mutect2, varscan2
- TBX5 | c.275C>A p.T92K | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV59858456, COSV59860596; called by muse, mutect2, varscan2
- TBXAS1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV54939889; called by muse, mutect2, varscan2
- TEP1 | c.4072G>T p.E1358* | Nonsense Mutation (SNP) | VAF 36/187 reads (19%) | catalogued as COSV52988000; called by muse, mutect2, varscan2
- TEX29 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99365925; called by muse, mutect2, varscan2
- TEX55 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs866104571, COSV55210182, COSV99817326; called by muse, mutect2
- TLR4 | c.2061G>A p.W687* (on ENST00000355622 / NM_138554.5; = p.W647* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV62922427; called by muse, mutect2, varscan2
- TMEM168 | c.1814G>T p.W605L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57179256; called by muse, mutect2, varscan2
- TMTC1 | c.2591C>A p.A864D (on ENST00000539277 / NM_001193451.2; = p.A756D on NM_175861.3) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55475266; called by muse, mutect2, varscan2
- TNXB | c.9943G>T p.V3315L (on ENST00000647633; = p.V3068L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV64473259; called by muse, mutect2, varscan2
- TOM1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV65897352; called by muse, mutect2, varscan2
- TOP2A | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70732033; called by muse, mutect2, varscan2
- TRBJ2-2 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as rs1554511418; called by muse, mutect2, varscan2
- TRERF1 | c.2806C>T p.R936W | Missense Mutation (SNP) | VAF 55/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs746577995, COSV61666981; called by muse, mutect2, varscan2
- TRIM4 | c.1265G>T p.S422I | Missense Mutation (SNP) | VAF 151/618 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV62468336; called by muse, mutect2, varscan2
- TXNDC15 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs201610354, COSV100613593, COSV64379295; called by muse, mutect2, varscan2
- UBA6 | c.1040G>T p.C347F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV59174367; called by muse, mutect2, varscan2
- UBIAD1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100954793, COSV100954884; called by muse, mutect2, varscan2
- UNC13C | c.5027C>T p.P1676L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.136); catalogued as rs1297963504, COSV52843474, COSV99514998; called by muse, mutect2, varscan2
- UNC5D | c.202A>T p.S68C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54769679; called by muse, mutect2, varscan2
- USH1G | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58880596; called by muse, mutect2, varscan2
- USH2A | c.6221C>G p.S2074C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as rs1296598016, COSV56323759, COSV56327499, COSV56414313; called by muse, mutect2, varscan2
- USH2A | c.2624C>A p.T875K | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.489); catalogued as COSV56327516; called by muse, mutect2, varscan2
- UTP20 | c.3580G>C p.E1194Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55372031; called by muse, mutect2, varscan2
- VCAM1 | c.1645C>A p.Q549K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV54117749; called by muse, mutect2, varscan2
- VEGFC | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54593674; called by muse, mutect2
- WDR53 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 149/444 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV60283552; called by muse, mutect2, varscan2
- YLPM1 | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV53106025; called by muse, mutect2, varscan2
- ZCCHC4 | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57180209; called by muse, mutect2, varscan2
- ZDHHC14 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV58193085; called by muse, mutect2, varscan2
- ZEB1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100313698, COSV58036441; called by muse, mutect2, varscan2
- ZIC1 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51550602; called by muse, mutect2, varscan2
- ZNF195 | c.1270G>T p.D424Y (on ENST00000399602 / NM_001130520.3; = p.D352Y on NM_007152.5) | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV99137595; called by muse, mutect2, varscan2
- ZNF202 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 238/401 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60246390; called by muse, mutect2, varscan2
- ZNF211 | c.1430G>T p.G477V (on ENST00000347302 / NM_198855.4; = p.G490V on NM_006385.5) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV53739918; called by muse, mutect2, varscan2
- ZNF225 | c.1677G>C p.Q559H | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV53470834, COSV53473424; called by muse, mutect2
- ZNF324B | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100351520; called by muse, mutect2, varscan2
- ZNF451 | c.2613A>T p.E871D | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.297); catalogued as COSV100674619; called by muse, mutect2, varscan2
- ZNF512 | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV62673760; called by muse, mutect2, varscan2
- ZNF804B | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60816160; called by muse, mutect2, varscan2
- ZYG11B | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs755302577, COSV53749963; called by muse, mutect2, varscan2
- ZZEF1 | c.2980A>G p.I994V | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV67555929; called by muse, mutect2, varscan2
- BLM | c.3260_3261dup p.V1088Lfs*11 | Frame Shift Ins (INS) | VAF 23/132 reads (17%) | called by mutect2, pindel, varscan2
- CEP55 | c.906_907del p.K303Dfs*9 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | called by pindel, varscan2
- CNTNAP3 | c.3706T>A p.L1236M | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DDX52 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- EML5 | c.5036dup p.E1680Rfs*7 (on ENST00000380664; = p.E1688Rfs*7 on NM_183387.3) | Frame Shift Ins (INS) | VAF 17/151 reads (11%) | called by mutect2, pindel, varscan2
- FBN2 | c.6254del p.P2085Lfs*164 | Frame Shift Del (DEL) | VAF 24/172 reads (14%) | called by mutect2, pindel, varscan2
- FCGBP | c.9343G>C p.G3115R | Missense Mutation (SNP) | VAF 35/455 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- GRM3 | c.1752del p.C585Vfs*11 | Frame Shift Del (DEL) | VAF 37/137 reads (27%) | called by mutect2, pindel, varscan2
- IVNS1ABP | c.1855_1872del p.F619_E624del | In Frame Del (DEL) | VAF 28/250 reads (11%) | called by mutect2, pindel
- KRTAP10-4 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2
- MNAT1 | c.310del p.E104Kfs*6 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- MROH5 | c.2186_2188del p.Q729del | In Frame Del (DEL) | VAF 40/132 reads (30%) | called by pindel, varscan2
- MYL10 | c.84_86del p.R30del | In Frame Del (DEL) | VAF 30/172 reads (17%) | called by mutect2, pindel, varscan2
- MYOZ2 | c.645dup p.D216Rfs*18 | Frame Shift Ins (INS) | VAF 21/152 reads (14%) | called by mutect2, pindel, varscan2
- PAQR6 | c.926del p.N309Tfs*126 (on ENST00000292291 / NM_001272108.2; = p.T227Pfs*41 on NM_024897.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/134 reads (16%) | called by mutect2, pindel, varscan2
- PCDHAC1 | c.2334del p.D779Tfs*9 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 67/622 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.346); called by muse, mutect2
- PRAMEF8 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRR27 | c.94del p.H32Tfs*7 | Frame Shift Del (DEL) | VAF 38/233 reads (16%) | called by mutect2, pindel, varscan2
- RBP3 | c.3024G>T p.K1008N | Missense Mutation (SNP) | VAF 133/335 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- TRGC2 | c.271A>T p.R91* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- ZNF181 | c.540del p.N181Ifs*8 | Frame Shift Del (DEL) | VAF 36/66 reads (55%) | called by mutect2, pindel, varscan2
- ACTL9 | c.372C>A p.A124= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as rs1555753456, COSV61004748; called by muse, mutect2, varscan2
- ADAM17 | c.672G>T p.T224= | Silent (SNP) | VAF 177/279 reads (63%) | catalogued as rs757777916, COSV100176260, COSV60397518; called by muse, mutect2, varscan2
- ADAM2 | c.540A>C p.I180= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55858779; called by muse, mutect2, varscan2
- AGRN | c.303C>T p.L101= | Silent (SNP) | VAF 94/410 reads (23%) | catalogued as rs1188654784, COSV65067715; called by muse, mutect2, varscan2
- AHCTF1 | c.1401A>T p.S467= (on ENST00000366508; = p.S441= on NM_015446.5) | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as COSV58245801; called by muse, mutect2, varscan2
- ARHGAP26 | c.1461T>A p.S487= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as COSV50824255; called by muse, mutect2, varscan2
- ARHGAP5 | c.3378A>G p.V1126= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV61533906; called by muse, mutect2, varscan2
- ARHGEF10 | c.525C>T p.I175= (on ENST00000398564; = p.I151= on NM_014629.4) | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as rs1476541681, COSV50642508; called by muse, mutect2, varscan2
- ASXL3 | c.3195G>T p.R1065= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV52457217, COSV52463812; called by muse, mutect2, varscan2
- BRINP2 | c.2178G>T p.R726= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as COSV100837830; called by muse, mutect2, varscan2
- CARD14 | c.753G>C p.L251= | Silent (SNP) | VAF 30/257 reads (12%) | catalogued as COSV60121616, COSV60125443; called by muse, mutect2, varscan2
- CDC20B | c.630T>C p.G210= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as rs149160251; called by muse, mutect2, varscan2
- CDR1 | c.262C>T p.L88= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV65163837; called by muse, mutect2, varscan2
- CHRD | c.2301T>C p.D767= | Silent (SNP) | VAF 35/207 reads (17%) | catalogued as COSV52605412; called by muse, mutect2, varscan2
- CHRNB4 | c.882C>T p.L294= | Silent (SNP) | VAF 34/181 reads (19%) | catalogued as rs1332050381, COSV55714630; called by muse, mutect2, varscan2
- CRCT1 | c.96G>T p.A32= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs773688163, COSV100524161; called by muse, varscan2
- CSF1R | c.1452G>A p.E484= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV53828439; called by muse, mutect2, varscan2
- DNAH3 | c.12249C>T p.G4083= | Silent (SNP) | VAF 147/368 reads (40%) | catalogued as COSV54503198; called by muse, mutect2, varscan2
- FAM153B | c.714G>A p.E238= (on ENST00000253490; = p.E161= on NM_001265615.1) | Silent (SNP) | VAF 40/518 reads (8%) | catalogued as COSV99498733; called by muse, mutect2
- FAN1 | c.2796C>T p.V932= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as rs775134056, COSV62949677; called by muse, mutect2, varscan2
- GATA2 | c.1026C>T p.A342= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as rs758279649, COSV100350888; called by muse, mutect2, varscan2
- GATAD2B | c.885C>T p.A295= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs1414330766, COSV64083152; called by muse, mutect2, varscan2
- GJA4 | c.304C>A p.R102= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100654620, COSV60726000; called by muse, mutect2, varscan2
- H2AC11 | c.72C>G p.L24= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV100345596; called by muse, mutect2, varscan2
- HECTD3 | c.438G>T p.A146= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2
- ICE1 | c.4014G>A p.Q1338= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV56819016; called by muse, mutect2, varscan2
- ITGAM | c.2619G>T p.P873= (on ENST00000648685 / NM_001145808.2; = p.P872= on NM_000632.4) | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV54933951; called by muse, mutect2, varscan2
- JAKMIP1 | c.2157C>T p.A719= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV101290846; called by muse, varscan2
- KCNH5 | c.1350G>C p.V450= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV59752142; called by muse, mutect2, varscan2
- KCNK10 | c.810G>T p.V270= | Silent (SNP) | VAF 75/169 reads (44%) | catalogued as COSV56639385; called by muse, mutect2, varscan2
- KIF19 | c.1176G>T p.R392= | Silent (SNP) | VAF 68/118 reads (58%) | catalogued as COSV100738942; called by mutect2, varscan2
- KLHDC7A | c.1740G>T p.P580= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV101272718; called by muse, mutect2
- KLHL30 | c.1164C>T p.D388= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1346536927, COSV59974135; called by muse, mutect2
- KRT5 | c.1320G>A p.Q440= | Silent (SNP) | VAF 51/355 reads (14%) | catalogued as rs759733947, COSV52858822; called by muse, mutect2, varscan2
- KRTAP13-3 | c.432C>A p.S144= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV61878519; called by muse, mutect2, varscan2
- LHFPL5 | c.369G>T p.T123= | Silent (SNP) | VAF 74/181 reads (41%) | catalogued as COSV100798925; called by muse, mutect2, varscan2
- MUC2 | c.2364C>A p.A788= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- NCAN | c.2283C>T p.F761= | Silent (SNP) | VAF 111/230 reads (48%) | catalogued as rs201602902, COSV53046737; called by muse, mutect2, varscan2
- NECTIN3 | c.1182G>A p.L394= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs201277209, COSV60549885; called by muse, mutect2, varscan2
- NFIL3 | c.1299G>A p.L433= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as COSV52682978; called by muse, mutect2, varscan2
- NID1 | c.2271C>A p.R757= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV51614896; called by muse, mutect2, varscan2
- NLRP5 | c.3189G>A p.R1063= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs765935265, COSV66762038; called by muse, mutect2, varscan2
- OLFM4 | c.1512T>A p.S504= | Silent (SNP) | VAF 50/91 reads (55%) | catalogued as COSV54575765; called by muse, mutect2, varscan2
- OR10H1 | c.249C>T p.A83= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs1367926405, COSV58470691; called by muse, mutect2, varscan2
- OR2T3 | c.129C>A p.A43= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV100613073; called by muse, mutect2, varscan2
- OR4C11 | c.555T>A p.L185= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV56352146; called by muse, mutect2, varscan2
- OR51Q1 | c.330C>T p.S110= | Silent (SNP) | VAF 142/241 reads (59%) | catalogued as COSV56177819; called by muse, mutect2, varscan2
- OR5M10 | c.579T>A p.R193= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV73242246; called by muse, mutect2, varscan2
- PAX4 | c.820C>T p.L274= | Silent (SNP) | VAF 89/307 reads (29%) | catalogued as COSV58387315; called by muse, mutect2, varscan2
- PCDH11X | c.3828C>A p.V1276= | Silent (SNP) | VAF 152/339 reads (45%) | catalogued as COSV100010621, COSV53442672; called by muse, mutect2, varscan2
- PCDHA2 | c.1263T>C p.Y421= | Silent (SNP) | VAF 58/330 reads (18%) | catalogued as COSV65364583; called by muse, mutect2, varscan2
- PCDHB11 | c.1878C>G p.T626= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as rs1288142578; called by muse, varscan2
- PIGG | c.2691G>T p.L897= (on ENST00000453061 / NM_001127178.3; = p.L889= on NM_017733.4) | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV56316085; called by muse, mutect2, varscan2
- PIK3AP1 | c.2205C>T p.L735= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1198626901, COSV59530326; called by muse, mutect2
- PLEKHG4 | c.2229G>T p.T743= | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as rs368485618, COSV58571105; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1041G>T p.G347= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs770473649, COSV100982343, COSV100982563; called by muse, mutect2, varscan2
- PRAME | c.1323T>C p.Y441= | Silent (SNP) | VAF 85/175 reads (49%) | catalogued as COSV67160948; called by muse, mutect2, varscan2
- PRKDC | c.5520C>T p.F1840= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1342379775, COSV58042662; called by muse, mutect2, varscan2
- PRR12 | c.1680C>T p.S560= (on ENST00000615927; = p.S1381= on NM_020719.3) | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as rs748835453, COSV101330558; called by muse, mutect2, varscan2
- PSG7 | c.1005C>G p.P335= | Silent (SNP) | VAF 164/302 reads (54%) | catalogued as COSV68444265; called by muse, mutect2, varscan2
- RYR3 | c.10080C>G p.S3360= (on ENST00000389232; = p.S3361= on NM_001036.6) | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV66777779; called by muse, mutect2, varscan2
- SAMD9L | c.1995A>G p.T665= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV59079392; called by muse, mutect2, varscan2
- SENP5 | c.120G>T p.L40= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV100051766, COSV60207884; called by muse, mutect2, varscan2
- SH2D1B | c.144T>C p.N48= | Silent (SNP) | VAF 30/200 reads (15%) | catalogued as COSV63391959; called by muse, mutect2, varscan2
- SLC8A3 | c.195G>T p.P65= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV63518954, COSV63521668; called by muse, mutect2, varscan2
- SMARCA5 | c.2907T>C p.V969= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV51642251; called by muse, mutect2
- SNCA | c.276T>A p.T92= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV61131717, COSV61137549; called by muse, mutect2, varscan2
- SP7 | c.657G>C p.G219= | Silent (SNP) | VAF 31/186 reads (17%) | catalogued as COSV58190419; called by muse, mutect2, varscan2
- SPTBN4 | c.2643C>T p.L881= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs1568795247, COSV58943447; called by muse, mutect2, varscan2
- SRMS | c.576G>A p.E192= | Silent (SNP) | VAF 195/628 reads (31%) | catalogued as COSV53919803; called by muse, mutect2, varscan2
- ST18 | c.2415C>A p.T805= | Silent (SNP) | VAF 73/235 reads (31%) | catalogued as COSV52484412; called by muse, mutect2, varscan2
- TECPR1 | c.879C>A p.V293= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV65782550; called by muse, mutect2, varscan2
- TEX14 | c.1530G>C p.L510= (on ENST00000240361 / NM_001201457.2; = p.L504= on NM_031272.5) | Silent (SNP) | VAF 37/280 reads (13%) | catalogued as COSV53611787; called by muse, mutect2, varscan2
- TRPC4 | c.1203C>A p.I401= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as COSV58990513, COSV58999028; called by muse, mutect2, varscan2
- TTI1 | c.3180C>G p.P1060= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as COSV65060429; called by muse, mutect2, varscan2
- USH2A | c.13599A>G p.S4533= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as COSV56327484; called by muse, mutect2, varscan2
- USP24 | c.3414C>T p.S1138= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53761862; called by muse, mutect2, varscan2
- VEZT | c.165A>G p.P55= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99703483; called by muse, mutect2, varscan2
- YTHDC2 | c.1464C>G p.V488= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV50736604, COSV99363404; called by muse, mutect2, varscan2
- ZFHX4 | c.1735C>A p.R579= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV50493219, COSV51498880; called by muse, mutect2, varscan2
- ZIM3 | c.609A>G p.A203= | Silent (SNP) | VAF 53/235 reads (23%) | catalogued as COSV54139909; called by muse, mutect2, varscan2
- ZNF106 | c.4548A>C p.P1516= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV55513688; called by muse, mutect2, varscan2
- ZNF536 | c.879C>T p.I293= | Silent (SNP) | VAF 179/370 reads (48%) | catalogued as COSV62818462; called by muse, mutect2, varscan2
- ZNF610 | c.78C>T p.F26= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV58343549; called by muse, mutect2
- ZNRF4 | c.693G>T p.S231= | Silent (SNP) | VAF 86/164 reads (52%) | catalogued as COSV99706342, COSV99706782; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154260 G>T | 3'Flank (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- ADARB2 | c.101-177702A>G | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- BIRC8 | n.1699C>A | RNA (SNP) | VAF 60/279 reads (22%) | catalogued as COSV58842652; called by muse, mutect2, varscan2
- CARMIL1 | c.614+1396G>T | Intron (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- KDM1A | c.518-5933G>C | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- KIF1B | c.2115+7030A>T | Intron (SNP) | VAF 72/277 reads (26%) | catalogued as rs1397031386, COSV55809613, COSV99822447; called by muse, mutect2, varscan2
- LRP5L | n.199C>T | RNA (SNP) | VAF 23/124 reads (19%) | catalogued as rs781339994, COSV101292717; called by muse, mutect2, varscan2
- PRKACB | c.47-34631C>G | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100854799; called by muse, mutect2, varscan2
- SDK1 | c.*3321G>A | 3'UTR (SNP) | VAF 180/558 reads (32%) | catalogued as rs778688730, COSV67362874; called by muse, mutect2, varscan2
- SNORA71E | n.59G>C | RNA (SNP) | VAF 94/358 reads (26%) | called by muse, mutect2, varscan2
- SNORD115-17 | n.22T>C | RNA (SNP) | VAF 145/686 reads (21%) | called by muse, mutect2, varscan2
- UBXN1 | c.844+31G>C | Intron (SNP) | VAF 65/299 reads (22%) | catalogued as COSV99583132; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23494G>A | Intron (SNP) | VAF 23/141 reads (16%) | catalogued as COSV59381744, COSV59396427; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-626C>A | Intron (SNP) | VAF 53/288 reads (18%) | catalogued as COSV100514175; called by muse, mutect2, varscan2
